Gene-level copy-number profile of tumor specimen C3N-02639-02 from CPTAC case C3N-02639, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.2 years (21,610 days).
Specimen C3N-02639-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5332747a-4083-41e1-8af8-a77a67c23e50.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02639-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/bd1a8ee4-6222-4fcb-b980-c592d4756276

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 25,047; copy number 2: 31,168; copy number 3: 1,476; copy number 4: 427; copy number 5: 199; copy number 6: 26; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,183,659–42,354,454, 5 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr10:87,659,613–88,584,530, 12 genes (within-gene range 0–1): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr13:60,214,352–60,276,006, 2 genes: LINC00434, TARDBPP2.
- chr15:77,660,052–77,668,074, 1 gene (within-gene range 0–1): LINGO1-AS2.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr17:36,165,681–36,457,535, 15 genes (within-gene range 0–1): TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J.
- chr17:65,457,541–65,458,408, 1 gene: LINC02563.
- chr22:28,883,572–29,191,808, 8 genes (within-gene range 0–1): ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 226 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,072,110–19,075,511, 1 gene, copy number 6 (within-gene range 2–6): AL137127.1.
- chr1:156,192,063–156,212,796, 2 genes, copy number 5: AL135927.1, SLC25A44.
- chr7:117,710,651–117,874,139, 1 gene, copy number 5 (within-gene range 4–5): CTTNBP2.
- chr8:39,451,045–39,522,852, 1 gene, copy number 7: ADAM3A.
- chr8:100,913,247–101,293,783, 14 genes, copy number 5: AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.1.
- chr11:26,667,020–27,363,234, 5 genes, copy number 5: SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34.
- chr11:70,467,856–71,252,577, 10 genes, copy number 5: SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr12:52,164,115–52,473,805, 25 genes, copy number 6: LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C.
- chr19:15,902,300–18,220,480, 134 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:48,954,815–49,211,836, 33 genes, copy number 5: BAX, AC026803.2, FTL, GYS1, RUVBL2, MIR6798, LHB, AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1, NTF6B, AC008687.5, CGB5, CGB8, AC008687.6, CGB7, AC008687.8, AC008687.7, AC008687.2, NTF4, AC008687.3, KCNA7, RN7SL708P, SNRNP70, LIN7B, C19orf73, PPFIA3, HRC, TRPM4.

Autosomal genes at a single copy (total copy number 1): 25,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
